TCGA case TCGA-W5-AA2J — Cholangiocarcinoma (TCGA-CHOL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Liver and intrahepatic bile ducts; Tissue source site: Mayo Clinic Rochester. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/3f7e0cbf-e48c-410a-9138-be9b373fef73

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 66 years; Vital status: Alive.

Diagnoses (1)
1. Cholangiocarcinoma: ICD-O-3 morphology code: 8160/3; ICD-10 code: C22.1; Tissue or organ of origin: Intrahepatic bile duct; Site of resection or biopsy: Biliary tract, NOS; Classification of tumor: primary; Age at diagnosis: 66.1 years (24,140 days); Year of diagnosis: 2012; AJCC staging edition: 7th; AJCC pathologic T: T4; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 916 days (2.5 years); Child pugh classification: A; Ishak fibrosis score: 6 - Established Cirrhosis.
   Pathology details: Consistent pathology review: Yes; Perineural invasion present: No; Vascular invasion present: No.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis.
   Recorded as not given: adjuvant Ablation or Embolization, NOS; adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.

Follow-up (2 entries)
- Days to follow up: 916 days (2.5 years); Disease response: Tumor Free.
- ECOG performance status: 0.

Molecular and laboratory tests
- CA19-9: 52 U/mL; Blood test normal range lower: 0; Blood test normal range upper: 55.
- Prothrombin time (INR, as labelled on the TCGA clinical form) 0.9 [Blood test normal range lower: 0.8; Blood test normal range upper: 1.2].
- Platelets 172 (unit not recorded by GDC) [Blood test normal range lower: 150; Blood test normal range upper: 450].
- Creatinine 0.7 mg/dL [Blood test normal range lower: 0.6; Blood test normal range upper: 1.1].
- Total Bilirubin 1 mg/dL [Blood test normal range lower: 0.1; Blood test normal range upper: 1].
- Albumin 4.1 (unit not recorded on the TCGA source form) [Blood test normal range lower: 3.5; Blood test normal range upper: 5].

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 63 kg; Height: 157 cm; BMI: 25.6.
- Timepoint category: Prior to Diagnosis; Risk factors: Primary Sclerosing Cholangitis.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-W5-AA2J-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT; Initial weight: 280 mg.
  Slide TCGA-W5-AA2J-01A-03-TSC: Section location: Top; Percent tumor cells: 65; Percent tumor nuclei: 65; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 35; Percent lymphocyte infiltration: 8; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 3.
- Sample TCGA-W5-AA2J-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: Tumor free; New tumor event diagnosis indicator: No.
- Primary pathology: Submitted tumor site: Bile duct; Histologic diagnosis: Cholangiocarcinoma, hilar/perihilar; Definitive surgical procedure: Lobectomy.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 916 days; disease-specific survival: no event (censored), 916 days; progression-free interval: no event (censored), 916 days.
